Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3MY, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3MY-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology.

Tel: _____

DOB: _____

Sex: M

Physician: _____

Accession: _____

Collected: _____

Received: _____

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA (1.5 CM) INVOLVING THE LEFT LOBE AND EXTENDING INTO THE PERITHYROID SOFT TISSUE AND SKELETAL MUSCLE.
Two follicular adenomas (0.8 cm), left lobe.
Adenomatoid colloid nodule, right lobe.
Margins of resection, free
- (B) LEFT CRICOTHYROID TISSUE:
PAPILLARY THYROID CARCINOMA IN FIBROUS TISSUE.
- (C) THYROID ARYTENOID:
Skeletal muscle and adipose tissue.
No tumor present.
- (D) THYROID CARTILAGE:
Pending section for decalcification.
Supplemental report will follow.

100-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9 1/7/12
lw

Entire report and diagnosis completed by _____

GROSS DESCRIPTION

- (A) TOTAL THYROIDECTOMY - A product of total thyroidectomy with marked adhesion and fibrosis with overall measurements of 8.0 x 4.5 x 2.5 cm. The right lobe is nodular, elongated and measures 6.0 x 2.5 x 1.4 cm, and the left lobe is irregular, fibrotic with marked adhesion and measures 4.5 x 3.0 x 2.5 cm. Multiple nodules are identified ranging in size from 0.4 to 1.7 cm are noted throughout the gland. The left lobe shows a fibrotic and firm nodule extending from the superior-to-inferior aspect of the lobe and involves the soft tissue and muscle surrounding the lobe and abutting the posterior aspect of the margin. The specimen is submitted entirely as follows. The right lobe was sequentially sectioned from superior to inferior under A1-A7, and the left lobe sequentially sectioned from superior to inferior under A8 to A24.
- (B) LEFT CRICOTHYROID TISSUE - Two soft tissue fragments measuring 0.5 x 0.5 x 0.2 cm each, entirely submitted for frozen in B.

*FS/DX: THYROID NEOPLASM IN FIBROUS TISSUE.

- (C) THYROID ARYTENOID - A small soft tissue fragment 1.5 x 0.3 x 0.4 cm. Submitted entirely under C.
- (D) THYROID CARTILAGE - A fragment of cartilage and bone submitted for decal under D.

Page 1 of 3

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,
Tel

DOB:
Physician:

Sex: M

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

ADDENDUM

Addendum completed by

DIAGNOSIS

(D) THYROID CARTILAGE:
PAPILLARY CARCINOMA OF THYROID INVOLVING CARTILAGE.

Released by:

Page 3 of 3

Surgical Pathology Report

File under: Pathology

Source: NCI Genomic Data Commons file e1d7e0be-9caa-4eee-9ed9-f80fd74a206c (TCGA-EL-A3MY.2F9CD81A-D55E-4C8A-8524-9FFA71F3B3C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).